Somatic mutation profile of tumor specimen TCGA-X7-A8M3-01A (aliquot TCGA-X7-A8M3-01A-11D-A423-09) from TCGA case TCGA-X7-A8M3, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 64.9 years (23,718 days).
Specimen TCGA-X7-A8M3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41bc5ec6-5dae-45f0-a5ea-d95c7bf96b53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8M3-10A (Blood Derived Normal), aliquot TCGA-X7-A8M3-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e60da80d-1be4-4682-87da-5c11adf03cdd

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Nonsense Mutation 6, Silent 5, Splice Site 1, Frame Shift Del 1, In Frame Ins 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXL | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV56563508; called by muse, mutect2, varscan2
- CBY1 | c.380G>T p.*127Lext*32 | Nonstop Mutation (SNP) | VAF 34/99 reads (34%) | catalogued as rs765329637, COSV53263782; called by muse, mutect2, varscan2
- CEP120 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773419230; called by muse, mutect2, varscan2
- EBF1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV58169176; called by muse, mutect2, varscan2
- MAGEB16 | c.206G>T p.C69F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.905); catalogued as rs1372239364; called by muse, mutect2, varscan2
- RFC3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761230186, COSV101197852; called by mutect2, varscan2
- RIMBP3 | c.3064C>A p.H1022N | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780839532; called by muse, mutect2, varscan2
- RPS6KA6 | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 114/226 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99423946; called by muse, mutect2, varscan2
- TOPORS | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV104418010; called by muse, mutect2, varscan2
- ZNF492 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 41/100 reads (41%) | catalogued as rs773140573; called by muse, mutect2, varscan2
- AC004997.1 | c.1377G>T p.V459= | Splice Region (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- APOA5 | c.811_813dup p.G271dup | In Frame Ins (INS) | VAF 10/12 reads (83%) | called by mutect2, varscan2
- L3MBTL3 | c.1856C>G p.A619G | Missense Mutation (SNP) | VAF 56/62 reads (90%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTBP1 | c.2573C>A p.S858Y (on ENST00000404816 / NM_206943.4; = p.S532Y on NM_000627.4) | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP6 | c.2189C>A p.T730K | Missense Mutation (SNP) | VAF 33/35 reads (94%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCFD2 | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAX5 | c.556_557delinsT p.G186Sfs*92 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by muse*, pindel
- PLXNA3 | c.3726C>A p.Y1242* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- POGLUT1 | c.620C>A p.A207E | Missense Mutation (SNP) | VAF 127/131 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PPWD1 | c.969+1del p.X323_splice | Splice Site (DEL) | VAF 55/140 reads (39%) | called by mutect2, pindel, varscan2
- RFXAP | c.429C>G p.Y143* | Nonsense Mutation (SNP) | VAF 26/28 reads (93%) | called by muse, mutect2
- SHC4 | c.1474C>A p.H492N | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC22A25 | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 30/34 reads (88%) | called by muse, mutect2, varscan2
- CLCN1 | c.687G>T p.V229= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV58374437; called by muse, mutect2
- DIS3L2 | c.543C>A p.I181= | Silent (SNP) | VAF 24/26 reads (92%) | called by muse, mutect2, varscan2
- DOCK1 | c.2697C>A p.T899= | Silent (SNP) | VAF 4/21 reads (19%) | called by mutect2, varscan2
- HSD11B2 | c.876G>A p.L292= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as rs765861384; called by muse, mutect2, varscan2
- PZP | c.612G>T p.V204= | Silent (SNP) | VAF 18/19 reads (95%) | called by muse, mutect2, varscan2
